Somatic mutation profile of tumor specimen ALCH-AE86-TTP1-A (aliquot ALCH-AE86-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE86, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.3 years (27,513 days).
Specimen ALCH-AE86-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cf60715-025e-44fb-8928-e920f1571522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE86-NB1-A (Blood Derived Normal), aliquot ALCH-AE86-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f16263fa-d8d2-4400-9760-f54dc34a8cab

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GDF3 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 30/718 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as rs758931622; called by muse, mutect2
- GRIA1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV53616525; called by muse, mutect2
- NLRP12 | c.3007C>T p.L1003F | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100145029; called by muse, mutect2
- NRCAM | c.2359C>A p.R787S (on ENST00000379028 / NM_001371124.1; = p.R771S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61043555; called by muse, mutect2
- ZFHX4 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 11/246 reads (4%) | catalogued as COSV51500308, COSV99254272, COSV99260823; called by muse, mutect2
- ABCB1 | c.2782T>A p.Y928N | Missense Mutation (SNP) | VAF 93/1057 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AK9 | c.5725A>G p.I1909V | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALPK3 | c.3208A>T p.T1070S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2
- DLX6 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH9 | c.10106T>A p.F3369Y | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2
- ERICH3 | c.2690A>G p.Q897R | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.08); called by muse, mutect2
- GPR143 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYAL1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.123); called by muse, mutect2
- LPAR4 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PCSK5 | c.4766G>T p.R1589I | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ZNF225 | c.1564A>T p.T522S | Missense Mutation (SNP) | VAF 18/509 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ZNF284 | c.665A>T p.Q222L | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ZRANB1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 16/530 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2
- F13A1 | c.1662C>T p.L554= | Silent (SNP) | VAF 13/378 reads (3%) | catalogued as CD043672; called by muse, mutect2
- JPH2 | c.1065G>A p.L355= | Silent (SNP) | VAF 10/260 reads (4%) | called by muse, mutect2
- KIR3DL1 | c.570A>T p.A190= | Silent (SNP) | VAF 14/322 reads (4%) | catalogued as COSV58491620; called by muse, mutect2
- NRCAM | c.2229C>A p.A743= (on ENST00000379028 / NM_001371124.1; = p.A727= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- PLCL1 | c.1857G>A p.E619= | Silent (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- RELN | c.8763T>A p.L2921= | Silent (SNP) | VAF 56/590 reads (9%) | called by muse, mutect2
- AC092687.1 | n.315G>A | RNA (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- ZNF211 | c.90+321C>G | Intron (SNP) | VAF 27/605 reads (4%) | called by muse, mutect2
